Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A2ND, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A2ND-06A (Metastatic).

FINAL DIAGNOSIS:

SKIN AND SOFT TISSUE, RIGHT FLANK, WIDE EXCISION -

~~METASTATIC MALIGNANT MELANOMA~~ IN SUBCUTANEOUS FIBROADIPOSE TISSUE (see comment).

Collection Date:

COMMENT:

The overlying skin is unremarkable. Immunohistochemical stains S100 and HMB 45 are positive, in tumor, confirming the above diagnosis.

ICD-0-3

Melanoma, NOS 8720/3

Site: Skin, flank C44.5

lw 8/19/11

Source: NCI Genomic Data Commons file b3826be2-f842-417f-b51c-664d1bdb80d5 (TCGA-ER-A2ND.790BDDA5-3565-4B59-8784-DE32AC75C38B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).